Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EC, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EC-01A (Primary Tumor).

[page 1 of 2]
Date of surgery :

Left eye enucleation

Macroscopy

Enucleation specimen measuring 24 mm in diameter, with a segment of optic nerve of 8 mm long. At the section presence of a black tumor measuring 9 mm main line. Samples have been made for cryopreservation and cytogenetic studies. The specimen has been then included entirely after fixation.

Microscopy

*See path discrepancy form for
epithelioid and spindle cell ratio.*

The lesion seen macroscopically has the morphological characteristics of a choroidal melanoma. This tumor proliferation is made of fusiform cells (95%) and of localized nest of epithelioid cells (<5%). These cells contain atypical nucleolated nuclei, with cytoplasm loaded with melanin pigment. They are organized in cluster or crisscrossing bundles. Mitotic figures are present (8 mitosis by 10 fields at the 400 magnification).the lesion measures 9 mm of main line. It is localized at the posterior pole, at the level of the emergence of the optic nerve, and infiltrates the internal third of the sclera without extra sclera extension. The ciliary processes, the optic foramen and the optic nerve on his entire course including the cut end, the meningeal sheaths and the extrasclérale tissues are free of tumor.

Conclusion

Choroidal melanoma with mostly fusiform cells

Size of the tumor: 9 mm main line

Infiltration of the internal third of the sclera without extrascléral extension

The meningeal sheaths and the extrasclérale tissue are free of tumor

ICD-O-3

*Melanoma, spindle cell
8772/3*

*Site @ Choroid
C69.3*

Q15 3/10/14

ICD-9A Discrepancy		
Case Selection		

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	<5% epithelioid cells 95% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% spindle cells 1-30% epithelioid cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file f062fd6c-ae20-4e16-a018-9017af2355a2 (TCGA-V4-A9EC.A2A74023-0861-4C39-B9D1-FC97AA980C5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).